Somatic mutation profile of tumor specimen 0DGMHQ from CCDI case PBBTDS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 7.1 years (2,593 days).
Specimen 0DGMHQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e29d5bd2-31c5-41fc-8035-d5fae62168c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGMHZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8ca677b-7784-41cb-83f0-0588fc624792

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 2, Silent 2, Intron 1, In Frame Del 1, Frame Shift Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.4600C>T p.R1534* (on ENST00000358273 / NM_001042492.3; = p.R1513* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 189/283 reads (67%) | catalogued as rs760703505, CM941093, COSV62191852; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.783_784del p.N262Qfs*35 | Frame Shift Del (DEL) | VAF 273/508 reads (54%) | catalogued as rs1554825249; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KNSTRN | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 212/326 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV51112406; called by muse, mutect2, varscan2
- MIB2 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 145/826 reads (18%) | catalogued as rs756116522; called by muse, mutect2, varscan2
- PLS1 | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 162/543 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- THOC2 | c.2966C>T p.S989L | Missense Mutation (SNP) | VAF 27/629 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- VPS50 | c.2185_2187del p.R729del | In Frame Del (DEL) | VAF 199/612 reads (33%) | called by mutect2, pindel, varscan2
- MRGPRX4 | c.12C>T p.T4= | Silent (SNP) | VAF 184/678 reads (27%) | catalogued as rs369423824; called by muse, mutect2
- NDST3 | c.2571G>A p.L857= | Silent (SNP) | VAF 225/323 reads (70%) | called by muse, mutect2, varscan2
- CRLS1 | c.-21C>A | 5'UTR (SNP) | VAF 63/233 reads (27%) | called by muse, mutect2, varscan2
- DLEC1 | c.2113-69C>G | Intron (SNP) | VAF 119/172 reads (69%) | called by muse, mutect2, varscan2
- PRSS8 | c.*22G>C | 3'UTR (SNP) | VAF 45/270 reads (17%) | called by muse, mutect2, varscan2
